Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABF, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABF-01A (Primary Tumor).

[page 1 of 2]
Surgery date:

Surgical Pathology

DIAGNOSIS:

A. Lymph node, common hepatic artery, biopsy: A single (1 of 1) lymph node is involved by adenocarcinoma.

ICD-O-3

B. Pancreas, neck margin, excision: Negative for tumor.

Adenocarcinoma, duct NOS 8500/3

C. Common hepatic duct, margin, excision: Negative for tumor.

Site: Pancreas head C25.0

gnd 5/5/14

D. Pancreatic head, duodenum, portion of jejunum, and gallbladder; pylorus-sparing Whipple resection: Invasive moderately to poorly differentiated (grade 3 of 4) ductal adenocarcinoma is identified forming a 3.2 x 3.0 x 2.0 cm solid mass located in the pancreatic head. The tumor extends beyond the pancreas to involve peripancreatic soft tissue. Angiolymphatic invasion is present. Perineural invasion is present. Tumor necrosis is absent. The uncinate margin is positive for invasive carcinoma. The remaining margins are uninvolved. The adjacent non-neoplastic pancreatic parenchyma shows chronic pancreatitis. Multiple (4 of 18) regional lymph nodes are positive for metastatic adenocarcinoma, including a common hepatic artery lymph node (see part A).

With available surgical material, [AJCC pT3N1] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "common hepatic artery lymph nodes" is a 2.7 x 1.2 x 0.5 cm lymph node. Lymph nodes submitted. Grossed by

B. Received fresh labeled "pancreatic neck margin" is a 3.2 x 1.5 x 0.3 cm fragment of tan pancreatic tissue with orientation. Margin submitted. Grossed by

C. Received fresh labeled "common hepatic duct margin" is a 1.0 x 1.0 x 0.3 cm fragment of tan soft tubular tissue with orientation. Margin submitted. Grossed by

D. Received fresh labeled "pancreatic head, duodenum, portion of jejunum, gallbladder" is a Whipple specimen consisting of 24.0 cm in length portion of duodenum, 8.5 x 4.3 x 3.5 cm portion of pancreas,

[page 2 of 2]
and a 9.0 x 4.5 x 1.0 cm gallbladder. The pancreatic uncinate margin is inked yellow and shaved. The portal vein groove is inked black and submitted perpendicularly. There is a 3.2 x 3.0 x 2.0 cm tan, firm diffusely infiltrative solid mass within the head of the pancreas at the uncinate margin. The mass extends to the peripancreatic soft tissue. A stent is present within the common bile duct. The gallbladder contains no choleliths. Peripancreatic and periduodenal lymph nodes are identified. Representative sections are submitted. Grossed by .

BLOCK SUMMARY:

Part A: Common hepatic artery lymph nodes

- 1 Comm hepatic artery LN(A1)

Part B: Pancreatic neck Margins

- 1 Pancreatic neck margin 1
- 2 Pancreatic neck margin 2

Part C: Common hepatic duct Margins

- 1 Common hepatic duct margin

Part D: Pancreatic head, duodenum, portion of jejunum, gallbladder

- 1 Uncinate margin 1
- 2 Uncinate margin 2
- 3 Uncinate margin 3
- 4 Portal vein groove margin
- 5 Pancreas tumor
- 6 Ampullary region
- 7 Pancreatic duct
- 8 Gallbladder
- 9 Peripancreatic LN 1(D1)
- 10 Peripancreatic LN 1(D2)
- 11 Peripancreatic LN 1(D3)
- 12 Peripancreatic LN 2(D4)
- 13 Peripancreatic LN 2(D5)
- 14 Peripancreatic LN2 (D6)
- 15 Peripancreatic LN2 (D7)
- 16 Peripancreatic LN2 (D8)
- 17 Peripancreatic LN1 (D9)
- 18 Peripancreatic LN3 (D10)
- 19 Peripancreatic LN1 (D11)
- 20 Peripancreatic LN 3(D12)
- 21 Peripancreatic LN 1(D13)
- 22 Peripancreatic LN 2(D14)
- 23 Peripancreatic LN 1(D15)
- 24 Peripancreatic LN 1(D16)
- 25 Pancreatic mass
- 26 Duodenal polyp

Source: NCI Genomic Data Commons file 14423f74-912a-4879-941c-0da340df34be (TCGA-2J-AABF.2482DBEA-2835-47AE-AD61-D53B6BB11271.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).